Somatic mutation profile of tumor specimen TCGA-13-2065-01A (aliquot TCGA-13-2065-01A-01D-1526-09) from TCGA case TCGA-13-2065, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.1 years (25,973 days).
Specimen TCGA-13-2065-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 241eb741-c545-460b-be77-2cb8111ea294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-2065-10A (Blood Derived Normal), aliquot TCGA-13-2065-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be0434ae-c8bb-47e4-8df6-1b594c6b18ea

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 32, Silent 13, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPI | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as rs778173995, COSV55016423; called by muse, varscan2
- ANO8 | c.3104C>A p.T1035N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.047); catalogued as COSV50202517; called by muse, mutect2, varscan2
- AXIN1 | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV51994397; called by muse, mutect2, varscan2
- CCDC186 | c.1300T>C p.C434R | Missense Mutation (SNP) | VAF 236/857 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65162265; called by muse, mutect2, varscan2
- CD200 | c.700G>A p.G234R (on ENST00000473539 / NM_001004196.3; = p.G209R on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV59862403; called by muse, mutect2, varscan2
- CIT | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 247/628 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs747310422, COSV55885461; called by muse, mutect2, varscan2
- CORO7 | c.950G>C p.R317P | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52033857, COSV52034580; called by muse, mutect2, varscan2
- ENOX2 | c.302T>C p.I101T (on ENST00000338144 / NM_001382520.1; = p.I72T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 230/684 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV57658869; called by muse, mutect2, varscan2
- EPAS1 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs375544083, COSV55390884; called by muse, mutect2, varscan2
- FAXC | c.249C>G p.H83Q | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as COSV67604088; called by muse, mutect2, varscan2
- FBH1 | c.565C>G p.P189A (on ENST00000362091 / NM_178150.3; = p.P240A on NM_032807.4) | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV62984769; called by muse, varscan2
- KRT28 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 118/161 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV60686705; called by muse, mutect2, varscan2
- MEFV | c.1645A>G p.T549A | Missense Mutation (SNP) | VAF 101/284 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV54828373; called by muse, mutect2, varscan2
- MID2 | c.752T>A p.V251D | Missense Mutation (SNP) | VAF 229/454 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV53314895; called by muse, mutect2, varscan2
- NKRF | c.1854C>A p.S618R | Missense Mutation (SNP) | VAF 119/364 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58663064; called by muse, mutect2, varscan2
- PALLD | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54996612; called by muse, mutect2, varscan2
- PANK4 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1366131245, COSV65868569; called by muse, mutect2, varscan2
- PAX5 | c.471C>G p.S157R | Missense Mutation (SNP) | VAF 304/816 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV63914192; called by muse, mutect2, varscan2
- RNF213 | c.1272-2A>G p.X424_splice | Splice Site (SNP) | VAF 199/241 reads (83%) | catalogued as rs753546396, COSV60631068; called by muse, mutect2, varscan2
- S100A7L2 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 152/289 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as COSV64195397, COSV64195690; called by muse, mutect2, varscan2
- SF3B4 | c.1150G>C p.G384R | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54967139; called by muse, mutect2, varscan2
- SLC16A3 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV66430231; called by muse, mutect2, varscan2
- SLCO6A1 | c.1430G>C p.C477S | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65815477; called by muse, mutect2, varscan2
- SPTBN4 | c.7666G>T p.D2556Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1278570602, COSV52544270; called by muse, mutect2, varscan2
- STK31 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 96/485 reads (20%) | catalogued as COSV63459933; called by muse, mutect2, varscan2
- SYN1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55985379; called by muse, mutect2, varscan2
- THUMPD3 | c.820A>T p.I274F | Missense Mutation (SNP) | VAF 160/218 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61506987; called by muse, mutect2, varscan2
- TLR5 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV60561108; called by muse, mutect2, varscan2
- TLR8 | c.1810A>T p.N604Y (on ENST00000218032 / NM_138636.5; = p.N622Y on NM_016610.4) | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54321334; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 50/78 reads (64%) | catalogued as rs587780067; called by pindel, varscan2
- TRMT11 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 43/189 reads (23%) | catalogued as COSV57674513; called by muse, mutect2, varscan2
- TSC22D2 | c.1455G>C p.Q485H | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV62623756; called by muse, mutect2, varscan2
- TULP1 | c.226C>G p.P76A | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV57694089; called by muse, mutect2, varscan2
- VAV2 | c.2093G>T p.R698M (on ENST00000371850 / NM_001134398.2; = p.R688M on NM_003371.4) | Missense Mutation (SNP) | VAF 106/154 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64085879; called by muse, mutect2, varscan2
- ZNF440 | c.1379G>A p.C460Y | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58372763; called by muse, mutect2, varscan2
- ZNF804B | c.2957C>G p.A986G | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100302065; called by muse, mutect2
- IMPG1 | c.1990_2015del p.A664Rfs*8 | Frame Shift Del (DEL) | VAF 89/558 reads (16%) | called by mutect2, pindel, varscan2
- TRAPPC8 | c.370_371delinsT p.E124Cfs*19 | Frame Shift Del (DEL) | VAF 48/155 reads (31%) | called by pindel, varscan2*
- C8A | c.1068G>C p.V356= | Silent (SNP) | VAF 98/290 reads (34%) | catalogued as rs200084020, COSV63486772; called by muse, mutect2, varscan2
- CASP4 | c.843G>A p.Q281= | Silent (SNP) | VAF 375/794 reads (47%) | catalogued as COSV67744968; called by muse, mutect2, varscan2
- FLG | c.6528G>A p.R2176= | Silent (SNP) | VAF 264/1455 reads (18%) | catalogued as COSV100910621; called by muse, mutect2
- KANK4 | c.1206C>T p.N402= | Silent (SNP) | VAF 160/445 reads (36%) | catalogued as rs142146326; called by muse, mutect2, varscan2
- L3MBTL1 | c.498G>A p.Q166= (on ENST00000418998 / NM_001377303.1; = p.Q76= on NM_015478.7) | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV64235472; called by muse, mutect2, varscan2
- MYF6 | c.237C>T p.I79= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV57353759; called by muse, mutect2, varscan2
- PALM | c.696G>A p.V232= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV52771361; called by muse, mutect2, varscan2
- PCDH15 | c.1992A>T p.S664= | Silent (SNP) | VAF 75/125 reads (60%) | catalogued as COSV57405665; called by muse, mutect2, varscan2
- PLSCR4 | c.987A>G p.R329= | Silent (SNP) | VAF 60/365 reads (16%) | catalogued as COSV100724124; called by muse, mutect2
- SCNN1D | c.1194G>A p.Q398= (on ENST00000338555; = p.Q562= on NM_001130413.4) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV57645061; called by muse, mutect2, varscan2
- SLC52A3 | c.1101C>T p.S367= | Silent (SNP) | VAF 138/361 reads (38%) | catalogued as rs539208778, COSV54076785; called by muse, mutect2, varscan2
- SMO | c.936G>T p.L312= | Silent (SNP) | VAF 195/692 reads (28%) | catalogued as COSV50847167; called by muse, varscan2
- ZFHX3 | c.9747G>T p.G3249= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV51739078; called by muse, mutect2, varscan2
